Somatic mutation profile of tumor specimen MP2PRT-PAUEAY-TMP1-A (aliquot MP2PRT-PAUEAY-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUEAY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,987 days).
Specimen MP2PRT-PAUEAY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b7386f6-d1f7-4b7a-8f9a-53726795a77a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUEAY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUEAY-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6eb5ec8e-d5e3-4092-b8cd-2d3837eb6ac2

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATR | c.4234C>T p.R1412* | Nonsense Mutation (SNP) | VAF 38/189 reads (20%) | catalogued as rs769216993; called by muse, mutect2, varscan2
- FBP1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 77/268 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); catalogued as rs768388780, COSV104427961; called by muse, mutect2, varscan2
- KMT2D | c.15742C>T p.Q5248* | Nonsense Mutation (SNP) | VAF 117/346 reads (34%) | catalogued as COSV56452637; called by muse, mutect2, varscan2
- SCN10A | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs371909817; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGM1 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 139/422 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs368781510; called by muse, mutect2, varscan2
- ARID4A | c.279T>A p.F93L | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CYTIP | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- JAG1 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 123/413 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- KREMEN2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 54/542 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, varscan2
- IGHV4-61 | chr14:106639118 GT>A | Silent (DEL) | VAF 38/261 reads (15%) | called by pindel, varscan2*
- NPHS1 | c.75G>A p.A25= | Silent (SNP) | VAF 124/437 reads (28%) | catalogued as rs774473854, COSV100799967; called by muse, mutect2, varscan2
- PCDH11X | c.2178C>T p.I726= | Silent (SNP) | VAF 85/164 reads (52%) | catalogued as rs770889015; called by muse, mutect2, varscan2
- IGLV4-69 | chr22:22031472 ins CC | 3'Flank (INS) | VAF 56/192 reads (29%) | called by pindel, varscan2
